CCDI case PBBISR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fbe6f7cb-c723-4748-8429-249d26fe53d8

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, anaplastic: ICD-O-3 morphology code: 9392/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 15.7 years (5,739 days).

Biospecimens (3 samples)
- Sample 0D9MK0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9MK1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9MK6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
